Surgical pathology report (de-identified scan), TCGA case TCGA-18-4721, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Princess Margaret Hospital (Canada), specimen TCGA-18-4721-01A (Primary Tumor).

[page 1 of 3]
TCGA-18-4721

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

- 1, 5th rib
- 2, Inferior pulmonary ligament ST9
- 3, Right TB angle ST10R
- 4, Station 5 subaortic
- 5, Anterior mediastinal ST6
- 6, LLL for bronchial margin

DIAGNOSIS

1. Portions of 5th rib -No gross pathology
- 2-5. Inferior pulmonary ligament ST9, right TB angle 10R, subaortic ST5 and anterior mediastinal ST6
lymph nodes - Negative for malignancy
6. Left lower lobe
- a) Invasive moderately-differentiated squamous cell carcinoma, peripheral but with no invasion of visceral pleura, 3.0 cm maximum dimension
- b) Bronchial margin of resection - Negative for malignancyOne interlobar, 3 lobar and one segmental lymph nodes - Negative for malignancy

COMMENT

Examination of this material indicates apparent complete resection of a T1N0 moderately-differentiated squamous cell carcinoma.

CLINICAL HISTORY

Status: complete

[page 2 of 3]
ZOO30 and ZOO40.

GROSS DESCRIPTION

1. The specimen container labelled with the patient's name and as "5th rib" contains six pieces of intact to fragmented grey-tan bony tissue with minimal associated soft tissue, received in 10% buffered formalin. The bone range in size from 1.0 x 0.2 x 0.1 cm to 6.0 x 1.6 x 0.7 cm. No gross abnormalities are identified. No tissue is submitted for histological examination.

2. The specimen container labelled with patient's name and as "inferior pulmonary ligament ST9" contains a piece of grey-black nodal tissue partly covered by fat. It measures 1.0 x 0.6 x 0.2 cm. It is submitted in toto in block 2A.

3. The specimen container labelled with the patient's name and as "right TB angle ST10R Q.S" contains a piece of grey-black nodal tissue with associated fatty tissue. The tissue measures 1.8 cm in diameter. It is bisected and examined in toto at intraoperative consultation - frozen section.

3A frozen section, resubmitted.

4. The specimen container labelled with the patient's name and as "ST5 subaortic Q.S" contains a grey-black lymph node measuring 0.7 cm in diameter. It was examined in toto at intraoperative consultation - frozen section.

4A frozen section, resubmitted

5. The specimen container labelled with the patient's name and as "anterior mediastinal ST6 QS" contains a dark grey node measuring 0.5 cm in diameter. It was examined in toto at intraoperative consultation - frozen section.

5A frozen section, resubmitted

6. The specimen container labelled with the patient's name and as "left lower lobe for bronchial margin Q.S" contains a lobe of lung received in 10% buffered formalin and measuring 16.0 x 10.5 x 7.0 cm in its formalin inflated state. A short segment of bronchus is attached measuring 1.2 cm long x 1.3 cm in diameter. The bronchial resection margin was examined in toto en-face at intraoperative consultation - frozen section in block 6A. One interlobar dark grey lymph node is identified measuring 1.8 cm

[page 3 of 3]
[REDACTED]

[REDACTED]

[REDACTED]

in diameter. One lobar lymph node is identified measuring 1.8 cm in diameter. Adjacent to the bronchus on the medial surface are two staple line margins measuring 3.9 cm and 10.0 cm. The pleura is smooth, shiny and grossly unremarkable. On sectioning the lung, there is a circumscribed, tan-black solid tumor mass measuring 3.0 x 2.3 x 2.5 cm. The mass is at the same level of the bronchus just lateral to it. The mass is approximately 3.0 cm away from the bronchial resection margin and 0.15 cm away from the pleural surface. There is no pleural involvement grossly. A representative section of tumor was examined at intraoperative consultation - frozen section in block 6B. A piece of tumor and a piece of normal lung tissue are taken for tissue frozen.

Sections are submitted as follows:

A	bronchial resection margin, frozen section resubmitted
6B	tumor, frozen section resubmitted
6C	one interlobar lymph node bisected
6D	one lobar lymph node bisected
6E	two lobar lymph nodes
6F	one segmental lymph node
6G, 6H	tumor closest to pleura with adjacent grossly normal parenchyma
6I	frozen section of tumor
6J	tumor closest to bronchial resection margin
6K	two sections of grossly normal parenchyma remote from tumor.

[REDACTED]

QUICK SECTION

3A, 4A, 5A "LYMPH NODES NEGATIVE FOR MALIGNANCY".
6A, bronchial resection margin "NEGATIVE"
6B, tumor "SQUAMOUS CELL CARCINOMA"

[REDACTED]

Source: NCI Genomic Data Commons file 1de3157a-8cbd-487b-a7a2-d3c3df7d719d (TCGA-18-4721.107FCB94-0216-4E11-90E0-31F2BDC044FB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).